Gene-level copy-number profile of tumor specimen HCM-WCMC-0753-C54-01A from HCMI case HCM-WCMC-0753-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.2 years (19,444 days).
Specimen HCM-WCMC-0753-C54-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fefb9551-e3e7-4d5f-ab45-db81f0759aa6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0753-C54-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/18bd5ea0-dca1-4a60-b11a-7b93857ac3b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2,228; copy number 2: 55,248; copy number 3: 779; copy number 4: 101; copy number 5: 13; copy number 6: 2; copy number 7: 4; copy number 8: 1; copy number 14: 3.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,766,540–143,769,083, 1 gene: FAM91A3P.
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr1:143,875,171–143,934,776, 4 genes (within-gene range 0–1): H2BP2, H3-2, AC246680.1, RPL22P5.
- chr6:26,686,241–26,687,964, 1 gene: AL513548.1.
- chr6:26,896,952–26,898,777, 1 gene (within-gene range 0–2): POM121L6P.
- chr7:56,991,888–57,009,149, 1 gene: TNRC18P3.
- chr7:63,509,303–63,562,588, 2 genes: PHKG1P2, SLC29A4P2.
- chr9:137,867,925–137,892,570, 1 gene (within-gene range 0–2): AL772363.1.
- chr16:15,094,411–15,131,601, 3 genes (within-gene range 0–2): AC139256.1, NPIPP1, PKD1P6-NPIPP1.
- chr16:15,358,978–15,381,047, 2 genes: AC137803.1, NPIPA5.
- chr16:70,852,698–70,852,814, 1 gene (within-gene range 0–2): RNU6ATAC25P.
- chr19:43,353,686–43,368,970, 2 genes: CD177, AC005392.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:181,178,821–181,206,120, 5 genes, copy number 5: LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3.
- chr14:18,333,726–18,596,310, 8 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr21:12,999,676–13,016,692, 1 gene, copy number 6: AP001464.1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 6–8 (within-gene range 1–8): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 7: AP001056.2, AP001056.1.
- chr21:44,217,014–44,262,216, 5 genes, copy number 7–14: ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Autosomal genes at a single copy (total copy number 1): 2,228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
